Somatic mutation profile of tumor specimen TCGA-B0-5117-01A (aliquot TCGA-B0-5117-01A-01D-1421-08) from TCGA case TCGA-B0-5117, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 40.0 years (14,612 days).
Specimen TCGA-B0-5117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa44495f-db22-4a39-aa5e-beed47b15774.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5117-11A (Solid Tissue Normal), aliquot TCGA-B0-5117-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbff8670-8948-408b-a1ca-54fc47cb2eea

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 39/74 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTR8 | c.441T>G p.I147M | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV51639060; called by muse, mutect2, varscan2
- MUC17 | c.7693C>A p.P2565T | Missense Mutation (SNP) | VAF 161/508 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV60306579; called by muse, mutect2, varscan2
- PKHD1 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as rs779418460, COSV61897605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKN3 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 16/548 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1017240248, COSV52580218, COSV99403687; called by muse, mutect2
- PLP2 | c.95_96insG p.I32Mfs*25 | Frame Shift Ins (INS) | VAF 16/24 reads (67%) | catalogued as COSV100890246; called by mutect2, varscan2
- SMC3 | c.2243A>C p.Q748P | Missense Mutation (SNP) | VAF 115/235 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.313); catalogued as COSV62422824; called by muse, mutect2, varscan2
- LARP4 | c.599_603del p.I200Nfs*3 | Frame Shift Del (DEL) | VAF 43/154 reads (28%) | called by pindel, varscan2
- NCOR2 | c.2538dup p.A847Rfs*3 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | called by pindel, varscan2
- ANXA10 | c.945C>A p.A315= | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as COSV63740767; called by muse, mutect2, varscan2
- SARDH | c.1392C>T p.Y464= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as rs781432712, COSV64099327; called by muse, mutect2
- SGCG | c.564G>T p.P188= | Silent (SNP) | VAF 95/298 reads (32%) | catalogued as rs367595212, COSV54570719; called by muse, mutect2, varscan2
- SLC16A13 | c.366C>T p.F122= | Silent (SNP) | VAF 56/107 reads (52%) | catalogued as rs776002559, COSV57275204; called by muse, mutect2, varscan2
- UQCR10 | c.30G>A p.L10= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV57459086; called by muse, mutect2, varscan2
